Somatic mutation profile of tumor specimen TCGA-AA-A00O-01A (aliquot TCGA-AA-A00O-01A-02W-A00E-09) from TCGA case TCGA-AA-A00O, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 83.0 years (30,316 days).
Specimen TCGA-AA-A00O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5564bde8-9877-44bf-a373-cdb0ebc94834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A00O-10A (Blood Derived Normal), aliquot TCGA-AA-A00O-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1f73edc-c3ce-468e-a205-0d6c657d1ced

The open-access MAF lists 89 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 63, Silent 19, Nonsense Mutation 5, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 72/163 reads (44%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.294_297del p.S99Rfs*23 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs730882015; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.91774C>T p.R30592* (on ENST00000591111; = p.R23168* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 98/257 reads (38%) | catalogued as rs781171206, COSV59886559; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.994G>A p.G332S (on ENST00000372530 / NM_001198934.2; = p.G289S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs745967911, COSV55084338; called by muse, mutect2, varscan2
- AKR1C4 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs531165422, COSV54122270; called by muse, mutect2
- ALDH6A1 | c.1201C>G p.P401A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63245758; called by muse, mutect2, varscan2
- ALG10B | c.1127C>A p.A376D | Missense Mutation (SNP) | VAF 56/565 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV58142262; called by muse, mutect2
- AP002512.3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs377523071, COSV54406015; called by muse, mutect2, varscan2
- C22orf42 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV66075230; called by muse, mutect2, varscan2
- CADPS | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 55/215 reads (26%) | catalogued as rs1411500518, COSV51866966; called by muse, mutect2, varscan2
- CBLB | c.1973G>C p.G658A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as COSV51421289; called by muse, mutect2, varscan2
- CBLL2 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs763838901, COSV60368365; called by muse, mutect2, varscan2
- CDRT1 | c.1781G>A p.G594D | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63052410; called by muse, mutect2, varscan2
- CFL1 | c.283A>C p.K95Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV57378410; called by muse, mutect2, varscan2
- CNTNAP4 | c.2294T>C p.V765A | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV56664837; called by muse, mutect2, varscan2
- CRYZ | c.522A>T p.L174F | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV61716899; called by muse, mutect2
- CYSLTR2 | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as COSV56165154, COSV56166053; called by muse, mutect2, varscan2
- DLC1 | c.745A>C p.T249P | Missense Mutation (SNP) | VAF 139/528 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1408820801, COSV52290290; called by muse, mutect2, varscan2
- DNAJA3 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV52160620; called by muse, mutect2, varscan2
- DPP10 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59664519; called by muse, mutect2, varscan2
- EMILIN2 | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs139273490; called by muse, mutect2, varscan2
- FADS2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53896772, COSV53902944; called by muse, mutect2, varscan2
- FAT4 | c.3505C>T p.R1169W | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs190175933; called by muse, mutect2, varscan2
- FOCAD | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV58093432; called by muse, mutect2, varscan2
- GPR32 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54513715; called by muse, mutect2, varscan2
- GRIK3 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs764550051, COSV66143169; called by muse, mutect2, varscan2
- HECTD3 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1557728786, COSV55798981; called by muse, mutect2, varscan2
- HYAL4 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 60/205 reads (29%) | catalogued as rs144025222; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV61142900; called by muse, mutect2, varscan2
- KCNA2 | c.473G>C p.S158T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV60368851; called by muse, mutect2, varscan2
- KRT222 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.102); catalogued as COSV67497728; called by muse, mutect2
- LHCGR | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs182707541, COSV54292551, COSV54297033, COSV54302848; called by muse, mutect2, varscan2
- LRP2 | c.10703C>T p.P3568L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs753477259, COSV55540802; ClinVar: uncertain significance; called by muse, mutect2
- LRRC4C | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs138717868; called by muse, mutect2, varscan2
- LTN1 | c.4408G>T p.D1470Y | Missense Mutation (SNP) | VAF 160/264 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV63732952; called by muse, mutect2, varscan2
- MS4A10 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV57632069; called by muse, mutect2, varscan2
- NCOA3 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 63/348 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV59065637; called by muse, mutect2, varscan2
- OR4A5 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV60521479; called by muse, mutect2, varscan2
- OR5M11 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as rs1344468286; called by muse, mutect2
- OR7D2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV60138800; called by muse, mutect2, varscan2
- OSBPL3 | c.2181del p.W728Gfs*65 | Frame Shift Del (DEL) | VAF 57/207 reads (28%) | catalogued as COSV57652628; called by mutect2, pindel, varscan2
- PKD2L1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58396760; called by muse, mutect2
- PRICKLE1 | c.1558T>C p.S520P | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV58203950; called by muse, mutect2, varscan2
- PXDNL | c.2741C>T p.S914L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV62477961; called by muse, mutect2, varscan2
- R3HDML | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53835159; called by muse, mutect2, varscan2
- RLIM | c.1306A>G p.N436D | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1350799772; called by muse, mutect2
- RNF175 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56840568; called by muse, mutect2, varscan2
- RYR3 | c.4852G>A p.A1618T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs777511024, COSV66777768; called by muse, mutect2, varscan2
- SCARA5 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs747795916, COSV61570864; called by muse, mutect2, varscan2
- SEMA3D | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1259776103, COSV52387440; called by muse, mutect2, varscan2
- SF3B1 | c.657T>A p.D219E | Missense Mutation (SNP) | VAF 138/446 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59206412; called by muse, mutect2, varscan2
- SPTBN1 | c.4970C>A p.A1657D | Missense Mutation (SNP) | VAF 77/591 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV61685507; called by muse, mutect2, varscan2
- SRRM2 | c.5517A>C p.R1839S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV57068133; called by muse, mutect2, varscan2
- SRSF4 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs539657602, COSV65694048; called by muse, mutect2
- ST6GALNAC5 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | PolyPhen benign (0.006); catalogued as rs781777501, COSV59561894; called by muse, mutect2, varscan2
- TNN | c.2633A>G p.D878G | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV53421600; called by muse, mutect2, varscan2
- UGT3A1 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs554821154, COSV57095384; called by muse, mutect2, varscan2
- VWF | c.8333G>A p.R2778Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs150577615; called by muse, mutect2
- ZKSCAN8 | c.1522C>A p.H508N | Missense Mutation (SNP) | VAF 54/490 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57636924; called by muse, mutect2
- ZNF214 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 93/684 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53480603; called by muse, mutect2, varscan2
- ZNF583 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as COSV52401006, COSV52403161; called by muse, mutect2, varscan2
- CRB1 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH2 | c.8206C>T p.L2736F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); called by muse, mutect2
- EHBP1L1 | c.4019C>A p.S1340* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- EIF2AK3 | c.2599C>T p.L867F | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2
- ELOVL4 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0.015); called by muse, mutect2
- INPP4B | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 66/1250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KIFC3 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MCAM | c.1469C>G p.P490R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.889); called by muse, mutect2
- PRAMEF18 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 88/583 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ABCC8 | c.636C>T p.D212= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV56846204; called by muse, mutect2, varscan2
- ATP1A4 | c.1896C>A p.A632= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as COSV100927639, COSV63625425; called by muse, mutect2, varscan2
- CCDC180 | c.1156C>T p.L386= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV63826770; called by muse, mutect2
- DIPK2B | c.1245G>A p.T415= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs762613094, COSV67640848; called by muse, mutect2, varscan2
- DSEL | c.1599G>A p.A533= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs767907230, COSV59489479; called by muse, mutect2, varscan2
- FBXO43 | c.906G>A p.P302= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs746267884, COSV71053288; called by muse, mutect2, varscan2
- HMOX2 | c.543G>T p.G181= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs200491627, COSV54859425; called by muse, mutect2, varscan2
- KCNT2 | c.2727C>A p.I909= | Silent (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- MUC16 | c.34404G>A p.G11468= | Silent (SNP) | VAF 25/440 reads (6%) | catalogued as COSV67450366; called by muse, mutect2
- NCAM1 | c.1734C>T p.P578= (on ENST00000316851 / NM_181351.5; = p.P568= on NM_000615.7) | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs78645852, COSV57510599; called by mutect2, varscan2
- OR8G2P | c.369T>C p.Y123= | Silent (SNP) | VAF 14/366 reads (4%) | catalogued as rs1165870473; called by muse, mutect2
- SAMHD1 | c.232C>T p.L78= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV53428232; called by muse, mutect2, varscan2
- SIGLEC14 | c.522A>C p.P174= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV55777380; called by muse, mutect2, varscan2
- SLIT1 | c.1392C>A p.A464= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV56582334; called by muse, mutect2, varscan2
- TAF11 | c.612G>A p.K204= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs1355312824; called by muse, mutect2, varscan2
- TET2 | c.1308C>T p.H436= | Silent (SNP) | VAF 133/495 reads (27%) | called by muse, mutect2, varscan2
- TRIP12 | c.2709T>G p.L903= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as rs202128964, COSV52259167; called by muse, mutect2, varscan2
- XRCC5 | c.474C>T p.D158= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV67534827; called by muse, mutect2, varscan2
- ZNF407 | c.4467C>A p.V1489= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV55242701; called by muse, mutect2, varscan2
